Somatic mutation profile of tumor specimen TARGET-20-PARLSL-09A (aliquot TARGET-20-PARLSL-09A-02D) from TARGET case TARGET-20-PARLSL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.2 years (4,456 days).
Specimen TARGET-20-PARLSL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e75c4ba-de79-433c-b739-bd91dd7fabc2.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARLSL-14A (Bone Marrow Normal), aliquot TARGET-20-PARLSL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cbeaaad-ff3e-436d-91e0-e58488aff1c7

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 2, Missense Mutation 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.7909C>T p.R2637* (on ENST00000358273 / NM_001042492.3; = p.R2616* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 107/419 reads (26%) | catalogued as rs786201367, CM950853, COSV62195872; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1382C>G p.A461G | Missense Mutation (SNP) | VAF 22/242 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397509344, COSV61005273; ClinVar: uncertain significance; called by muse, mutect2
- NPM1 | c.863_864insTCAG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 31/86 reads (36%) | catalogued as COSV51544444, COSV51555499, COSV51560925, COSV51570713; called by mutect2, pindel, varscan2
- NF1 | c.1219_1222del p.H407Mfs*4 | Frame Shift Del (DEL) | VAF 74/313 reads (24%) | called by mutect2, pindel, varscan2
- RAD21 | c.1497dup p.P500Tfs*37 | Frame Shift Ins (INS) | VAF 74/294 reads (25%) | called by mutect2, pindel, varscan2
